Gene-level copy-number profile of tumor specimen C3N-01083-02 from CPTAC case C3N-01083, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2.
Specimen C3N-01083-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 16a4a35c-13ae-4c49-a5f6-afd9118e8db6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01083-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/30388a3a-c06b-4746-bad4-2c667da62923

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 2,152; copy number 2: 53,722; copy number 3: 2,480; copy number 4: 4; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:100,492,619–102,479,841, 36 genes: TMEM45A, ADGRG7, AC069223.1, GMFBP1, TFG, ABI3BP, AC080014.1, RNU6-865P, ACTR3P3, IMPG2, SENP7, ZNF90P1, AC110994.1, AC110994.2, Y_RNA, FAM172BP, TRMT10C, PCNP, AC073861.1, AC084198.1, RNU6-1256P, Y_RNA, Y_RNA, ZBTB11, RNY1P12, ZBTB11-AS1, RPL24, PDCL3P4, CEP97, NXPE3, AC020651.1, NFKBIZ, LINC02085, Y_RNA, AC106712.1, ZPLD1.
- chr12:132,623,753–132,714,912, 3 genes (within-gene range 0–3): POLE, PXMP2, AC135586.2.
- chr21:43,092,956–43,115,709, 2 genes: U2AF1, MRPL51P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,047,695–242,084,233, 1 gene, copy number 6 (within-gene range 2–6): LINC01880.

Autosomal genes at a single copy (total copy number 1): 2,152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
